TCGA case TCGA-AA-3966 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bc42fe2d-1a33-428d-a601-b1871f4c8d9b

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 89 years; Vital status: Alive.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Hepatic flexure of colon; Classification of tumor: primary; Age at diagnosis: 89.1 years (32,537 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 61 days.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 14; Lymphatic invasion present: Yes; Vascular invasion present: Yes.

Follow-up (1 entry)
- Days to follow up: 61 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-3966-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.6; Shortest dimension: 0.2.
  Slide TCGA-AA-3966-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
  Slide TCGA-AA-3966-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-AA-3966-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AA-3966-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Colon Mucinous Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Anatomic organ subdivision: Hepatic Flexure; Lymph nodes examined: Yes; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Mismatch rep proteins tested by IHC: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 61 days; disease-specific survival: no event (censored), 61 days; progression-free interval: no event (censored), 61 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AA-3966-01A-01D-1427-01): tumor purity 0.51, ploidy 3.62, whole-genome doublings 1.
